Somatic mutation profile of tumor specimen C3L-07146-03 (aliquot CPT0461480006) from CPTAC case C3L-07146, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 82.8 years (30,255 days).
Specimen C3L-07146-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22db5770-7fee-4d36-8507-59f1be826f19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07146-71 (Blood Derived Normal), aliquot CPT0460150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/551e31fc-b2df-42cd-a933-9be83a8884cd

The open-access MAF lists 388 somatic variants for this specimen: 279 protein-altering or splice-affecting, 93 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 260, Silent 93, Nonsense Mutation 12, Intron 10, Splice Region 3, Translation Start Site 2, 5'UTR 2, 3'Flank 2, Splice Site 1, RNA 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.170A>C p.K57T | Missense Mutation (SNP) | VAF 24/366 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1057519909, COSV61068437; ClinVar: likely pathogenic; called by muse, mutect2
- NF2 | c.1604T>C p.L535P | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs74315493, CM950859; ClinVar: pathogenic; called by muse, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 26/280 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ALOX12B | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 44/322 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs150641093, COSV104406588; called by muse, mutect2, varscan2
- ANKRD6 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 50/299 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1326463830; called by muse, mutect2, varscan2
- ARHGEF17 | c.2608C>T p.R870W | Missense Mutation (SNP) | VAF 48/430 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs1166686049; called by muse, mutect2, varscan2
- ARID1A | c.1762C>T p.Q588* | Nonsense Mutation (SNP) | VAF 49/329 reads (15%) | catalogued as COSV61376986, COSV61381934; called by muse, mutect2, varscan2
- ASAH2 | c.851T>C p.L284S | Missense Mutation (SNP) | VAF 33/276 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1486785473; called by muse, mutect2, varscan2
- ASAP1 | c.3161C>T p.T1054M | Missense Mutation (SNP) | VAF 21/229 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs376556200; called by muse, mutect2
- ATAD3C | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 52/378 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs761654916; called by muse, mutect2, varscan2
- BASP1 | c.551A>G p.K184R | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as rs748574881; called by muse, mutect2, varscan2
- C1QBP | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 39/343 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.459); catalogued as rs1001036395, COSV56580012; called by muse, mutect2, varscan2
- C5orf49 | c.421T>G p.F141V | Missense Mutation (SNP) | VAF 28/281 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV57867163; called by muse, mutect2, varscan2
- CCL21 | c.370A>G p.R124G | Missense Mutation (SNP) | VAF 66/506 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs368229543; called by muse, mutect2, varscan2
- CEP135 | c.944T>G p.L315R | Missense Mutation (SNP) | VAF 25/321 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762230792; called by muse, mutect2
- CFAP206 | c.452A>G p.K151R | Missense Mutation (SNP) | VAF 17/247 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV99739695; called by muse, mutect2
- CFAP54 | c.1441T>C p.S481P | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs1259934483; called by muse, mutect2, varscan2
- CLUH | c.2581G>A p.A861T (on ENST00000435359; = p.A900T on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/320 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.227); catalogued as rs368569828; called by muse, mutect2, varscan2
- CNGA3 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 33/301 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV55622943, COSV99737058; called by muse, mutect2, varscan2
- COG7 | c.2000A>G p.Q667R | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as rs547230744; called by muse, mutect2, varscan2
- COL12A1 | c.2742A>C p.K914N | Missense Mutation (SNP) | VAF 33/311 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.24); catalogued as COSV59396157; called by muse, mutect2, varscan2
- CPQ | c.152T>C p.I51T | Missense Mutation (SNP) | VAF 35/329 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1321861762; called by muse, mutect2, varscan2
- CSF1R | c.732C>T p.L244= | Splice Region (SNP) | VAF 19/190 reads (10%) | catalogued as rs755892564, COSV53828263; called by muse, mutect2, varscan2
- CUX1 | c.4102C>T p.R1368W | Missense Mutation (SNP) | VAF 48/324 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV99469963; called by muse, mutect2, varscan2
- CYP4F8 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 24/334 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs755993126, COSV57853442; called by muse, mutect2
- DACH2 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 69/334 reads (21%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV64188049; called by muse, mutect2, varscan2
- DCAF4 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as rs763928317, COSV62319717; called by muse, mutect2, varscan2
- DNAH10 | c.6353C>T p.S2118L (on ENST00000409039; = p.S2057L on NM_207437.3) | Missense Mutation (SNP) | VAF 49/391 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as rs1018646580, COSV68993704; called by muse, mutect2, varscan2
- DNAH9 | c.13088C>T p.T4363M | Missense Mutation (SNP) | VAF 37/304 reads (12%) | SIFT tolerated (0.88); PolyPhen benign (0.019); catalogued as rs374943314; called by muse, mutect2, varscan2
- DOCK10 | c.2804A>C p.K935T | Missense Mutation (SNP) | VAF 36/361 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.584); catalogued as COSV51362317; called by muse, mutect2
- EFHB | c.1390T>G p.S464A | Missense Mutation (SNP) | VAF 38/247 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV55546647; called by muse, mutect2, varscan2
- EFNB1 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 88/406 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs761232213; called by muse, mutect2, varscan2
- FERMT1 | c.1595T>A p.L532Q | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99451417; called by muse, mutect2, varscan2
- GALNT17 | c.911T>G p.I304S | Missense Mutation (SNP) | VAF 32/422 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.223); catalogued as COSV61172284; called by muse, mutect2
- GPC6 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 45/328 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs760150200, COSV65500771, COSV65503817; called by muse, mutect2, varscan2
- GPR148 | c.626C>T p.T209I | Missense Mutation (SNP) | VAF 54/458 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs754230523; called by muse, mutect2, varscan2
- GPR39 | c.1322A>G p.N441S | Missense Mutation (SNP) | VAF 37/298 reads (12%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs749253009; called by muse, mutect2, varscan2
- GPR88 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 52/378 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV59292096; called by muse, mutect2, varscan2
- HMCN1 | c.11530C>A p.L3844I | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.991); catalogued as rs754718337; called by muse, mutect2, varscan2
- HTR3B | c.1190A>G p.Q397R | Missense Mutation (SNP) | VAF 45/391 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as rs1368033736; called by muse, mutect2, varscan2
- ITPR1 | c.4094G>A p.R1365Q (on ENST00000354582; = p.R1350Q on NM_002222.7) | Missense Mutation (SNP) | VAF 28/395 reads (7%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.997); catalogued as rs753284214, COSV56980695; called by muse, mutect2
- KCNV2 | c.929T>C p.M310T | Missense Mutation (SNP) | VAF 120/324 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs747021960; called by muse, mutect2, varscan2
- KIAA1210 | c.2817C>A p.S939R | Missense Mutation (SNP) | VAF 55/570 reads (10%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.922); catalogued as COSV101274326, COSV68176668; called by muse, mutect2, varscan2
- KPRP | c.757A>G p.S253G | Missense Mutation (SNP) | VAF 41/426 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1215259966; called by muse, mutect2
- LAMA2 | c.866G>A p.C289Y | Missense Mutation (SNP) | VAF 31/334 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101370329; called by muse, mutect2
- MAGI3 | c.1211T>G p.L404R | Missense Mutation (SNP) | VAF 28/299 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104409781; called by muse, mutect2
- MAP3K1 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 42/355 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.996); catalogued as COSV99063979; called by muse, mutect2, varscan2
- MED12L | c.4790G>A p.R1597H | Missense Mutation (SNP) | VAF 27/314 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs867946663, COSV56393102; called by muse, mutect2
- MUC6 | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 25/330 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.391); catalogued as rs1329049271; called by muse, mutect2
- MXRA5 | c.4148C>G p.S1383* | Nonsense Mutation (SNP) | VAF 88/416 reads (21%) | catalogued as COSV54233684, COSV54246466; called by muse, mutect2, varscan2
- MYH3 | c.5332G>A p.A1778T | Missense Mutation (SNP) | VAF 19/406 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as rs1272471978, COSV56867624; called by muse, mutect2
- NAIP | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 43/744 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1213270209; called by muse, mutect2
- NELL1 | c.1405G>T p.V469L | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV54263637, COSV54268287; called by muse, mutect2, varscan2
- NHSL2 | c.1760C>T p.A587V (on ENST00000510661; = p.A953V on NM_001013627.2) | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs953091038; called by muse, mutect2, varscan2
- NME5 | c.540A>C p.K180N | Missense Mutation (SNP) | VAF 18/235 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1322572453; called by muse, mutect2
- NRXN3 | c.2080A>C p.M694L (on ENST00000335750 / NM_001330195.2; = p.M321L on NM_004796.6) | Missense Mutation (SNP) | VAF 27/249 reads (11%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.816); catalogued as rs1389133926; called by muse, mutect2, varscan2
- NSD1 | c.1573C>T p.R525W | Missense Mutation (SNP) | VAF 42/387 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.549); catalogued as rs1215568879, COSV61775264; called by muse, mutect2, varscan2
- OGFRL1 | c.956A>C p.Q319P | Missense Mutation (SNP) | VAF 53/421 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs201295197, COSV64972450; called by muse, mutect2, varscan2
- OR2AP1 | c.574C>G p.L192V | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.043); catalogued as rs1358994022; called by muse, mutect2, varscan2
- PAK6 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 56/464 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs1303293188, COSV53044572; called by muse, mutect2, varscan2
- PGLS | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 46/432 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs781388754; called by muse, mutect2, varscan2
- PHF24 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 41/536 reads (8%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs774639353, COSV54275306; called by muse, mutect2
- PKHD1L1 | c.7982A>C p.E2661A | Missense Mutation (SNP) | VAF 36/286 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV101005359; called by muse, mutect2, varscan2
- PLXNA3 | c.2609G>A p.R870Q | Missense Mutation (SNP) | VAF 85/448 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.072); catalogued as rs368644346, COSV63754384; called by muse, mutect2, varscan2
- PLXNB3 | c.4303G>A p.V1435M | Missense Mutation (SNP) | VAF 38/337 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs782577261, COSV62796698; called by muse, mutect2, varscan2
- PNPLA7 | c.3150C>T p.D1050= | Splice Region (SNP) | VAF 22/257 reads (9%) | catalogued as rs1266596136; called by muse, mutect2
- POTEF | c.2540G>A p.R847H | Missense Mutation (SNP) | VAF 50/358 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.197); catalogued as rs751286635; called by muse, varscan2
- PRDM6 | c.1129C>A p.Q377K | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.237); catalogued as rs969142747; called by muse, mutect2, varscan2
- PTPRT | c.1648C>T p.H550Y | Missense Mutation (SNP) | VAF 45/486 reads (9%) | SIFT tolerated (0.88); PolyPhen benign (0.323); catalogued as rs751307703; called by muse, mutect2
- RB1 | c.1846A>G p.K616E | Missense Mutation (SNP) | VAF 39/265 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as CM012654; called by muse, mutect2, varscan2
- RBM48 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 26/321 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.15); catalogued as rs370287786; called by muse, mutect2
- RERGL | c.526T>G p.F176V | Missense Mutation (SNP) | VAF 35/323 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs1216805604; called by muse, mutect2, varscan2
- RIC8B | c.1396T>C p.W466R | Missense Mutation (SNP) | VAF 32/359 reads (9%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.891); catalogued as rs748396389; called by muse, mutect2
- RPA4 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 50/309 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as rs375731658, COSV61267138; called by muse, mutect2
- SLC25A15 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs747998866, COSV58556885, COSV58558173; ClinVar: uncertain significance; called by muse, mutect2
- SMAD4 | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100747627; called by muse, mutect2, varscan2
- SMARCC2 | c.2906C>T p.S969F | Missense Mutation (SNP) | VAF 40/463 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.36); catalogued as rs1203017760, COSV104386132; called by muse, mutect2
- SP9 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 46/409 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as rs760661767; called by muse, mutect2
- STRN | c.1748G>A p.R583H | Missense Mutation (SNP) | VAF 39/334 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs1421861423; called by muse, mutect2, varscan2
- TDRD5 | c.2645C>T p.A882V | Missense Mutation (SNP) | VAF 43/374 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs754332603; called by muse, mutect2, varscan2
- TECTB | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 33/400 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.195); catalogued as rs765710572, COSV65594556; called by muse, mutect2
- TENM3 | c.6593G>A p.R2198H | Missense Mutation (SNP) | VAF 30/395 reads (8%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.98); catalogued as rs201676320, COSV69308961, COSV69312882; called by muse, mutect2
- TET1 | c.2617G>A p.V873I | Missense Mutation (SNP) | VAF 32/269 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs199844508, COSV65382410; called by muse, mutect2, varscan2
- TPBG | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 26/392 reads (7%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.037); catalogued as rs747570726, COSV63882877; called by muse, mutect2
- TTN | c.46421G>A p.G15474D (on ENST00000591111; = p.G8050D on NM_003319.4) | Missense Mutation (SNP) | VAF 51/363 reads (14%) | PolyPhen benign (0.43); catalogued as rs796362520; called by muse, mutect2, varscan2
- TTPAL | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 38/343 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs1324848617; called by muse, mutect2, varscan2
- UBR4 | c.5686C>T p.R1896W | Missense Mutation (SNP) | VAF 41/375 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1557833707, COSV64392445; called by muse, mutect2, varscan2
- USP17L15 | c.929C>T p.T310M | Missense Mutation (SNP) | VAF 49/406 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as rs753088606; called by muse, mutect2, varscan2
- ZDHHC1 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 21/307 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs571642362, COSV62214588; called by muse, mutect2
- ZNF804B | c.1612A>G p.T538A | Missense Mutation (SNP) | VAF 32/257 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs774267760; called by muse, mutect2, varscan2
- AC005833.1 | c.1447A>G p.S483G | Missense Mutation (SNP) | VAF 34/320 reads (11%) | SIFT tolerated, low confidence (0.34); called by muse, mutect2, varscan2
- AC006059.2 | c.1171A>T p.S391C | Missense Mutation (SNP) | VAF 29/324 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- AC025287.4 | c.205A>C p.N69H | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- AC093155.3 | c.870T>C p.H290= | Splice Region (SNP) | VAF 21/266 reads (8%) | called by muse, mutect2
- ACSM6 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.173); called by muse, mutect2
- ACVR2A | c.548C>A p.P183H | Missense Mutation (SNP) | VAF 32/237 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ADAM7 | c.967T>G p.L323V | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ADAMTS9 | c.4256A>C p.D1419A | Missense Mutation (SNP) | VAF 35/344 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- ADGRB1 | c.4421A>C p.K1474T | Missense Mutation (SNP) | VAF 43/343 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AKAP14 | c.268_269del p.V90Ffs*2 | Frame Shift Del (DEL) | VAF 50/271 reads (18%) | called by pindel, varscan2
- ALB | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 37/375 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ALX4 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 41/311 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- ANKRD12 | c.3481A>C p.S1161R | Missense Mutation (SNP) | VAF 27/236 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AP2A2 | c.545T>C p.L182P | Missense Mutation (SNP) | VAF 40/351 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- APLF | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 43/393 reads (11%) | called by muse, mutect2, varscan2
- ARAP2 | c.3262A>G p.R1088G | Missense Mutation (SNP) | VAF 27/256 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- ASTN1 | c.3834G>T p.E1278D | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATG2A | c.1940T>G p.F647C | Missense Mutation (SNP) | VAF 47/467 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATP10B | c.3985T>C p.S1329P | Missense Mutation (SNP) | VAF 33/279 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ATP2C1 | c.1043G>A p.C348Y | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BLK | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 32/328 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- BRD7 | c.266A>C p.K89T | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- BSN | c.3061C>T p.Q1021* | Nonsense Mutation (SNP) | VAF 30/393 reads (8%) | called by muse, mutect2
- BUD23 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 29/276 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- C2CD3 | c.3608T>G p.I1203S | Missense Mutation (SNP) | VAF 30/257 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C4orf54 | c.4354A>C p.T1452P | Missense Mutation (SNP) | VAF 39/295 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1D | c.2203C>T p.L735F (on ENST00000350061 / NM_001128840.3; = p.L755F on NM_000720.4) | Missense Mutation (SNP) | VAF 29/234 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CAPSL | c.483A>C p.K161N | Missense Mutation (SNP) | VAF 42/450 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.014); called by muse, mutect2
- CAPZA2 | c.134T>G p.L45R | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CASK | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 57/284 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC39 | c.587T>G p.L196R | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); called by muse, mutect2
- CDH8 | c.343A>C p.T115P | Missense Mutation (SNP) | VAF 40/394 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- CLK3 | c.1592T>C p.L531P (on ENST00000395066 / NM_001130028.1; = p.L383P on NM_003992.4) | Missense Mutation (SNP) | VAF 26/273 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNKSR3 | c.1107T>G p.S369R | Missense Mutation (SNP) | VAF 32/278 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- COL4A4 | c.2268A>C p.K756N | Missense Mutation (SNP) | VAF 33/349 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2
- COL4A5 | c.485T>G p.I162S | Missense Mutation (SNP) | VAF 39/349 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- COL4A6 | c.254T>A p.L85Q | Missense Mutation (SNP) | VAF 25/346 reads (7%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.505); called by muse, mutect2
- CR1 | c.2725A>T p.S909C | Missense Mutation (SNP) | VAF 45/444 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- CTNNB1 | c.1997A>C p.K666T | Missense Mutation (SNP) | VAF 40/320 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CUBN | c.5047T>G p.L1683V | Missense Mutation (SNP) | VAF 31/286 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CUX2 | c.1076A>T p.Q359L | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- CYFIP1 | c.2551T>G p.F851V | Missense Mutation (SNP) | VAF 32/297 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.557); called by mutect2, varscan2
- DEPP1 | c.325T>G p.F109V | Missense Mutation (SNP) | VAF 51/394 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by mutect2, varscan2
- DOCK7 | c.4030C>G p.L1344V (on ENST00000635253 / NM_001367561.1; = p.L1313V on NM_033407.3) | Missense Mutation (SNP) | VAF 41/342 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DOP1B | c.4963A>C p.K1655Q | Missense Mutation (SNP) | VAF 32/281 reads (11%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- DSP | c.2885A>T p.E962V | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ECT2L | c.1292T>G p.I431S | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.193); called by muse, mutect2
- EDNRB | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 44/381 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELAVL3 | c.261T>G p.Y87* | Nonsense Mutation (SNP) | VAF 36/258 reads (14%) | called by mutect2, varscan2
- EMB | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 36/390 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- ENPP2 | c.1837T>G p.L613V (on ENST00000075322 / NM_001040092.3; = p.L665V on NM_006209.5) | Missense Mutation (SNP) | VAF 45/297 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EPB41L2 | c.1520A>G p.K507R | Missense Mutation (SNP) | VAF 35/275 reads (13%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ERLIN2 | c.845A>C p.Q282P | Missense Mutation (SNP) | VAF 24/289 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); called by muse, mutect2
- ERV3-1 | c.617A>C p.E206A | Missense Mutation (SNP) | VAF 47/413 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2
- EVX1 | c.14A>G p.K5R | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- F11 | c.257T>C p.L86P | Missense Mutation (SNP) | VAF 29/296 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2
- F8 | c.4069A>C p.T1357P | Missense Mutation (SNP) | VAF 84/444 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- FAM124A | c.1220A>G p.E407G (on ENST00000322475 / NM_001242312.2; = p.E443G on NM_145019.4) | Missense Mutation (SNP) | VAF 42/507 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2
- FANCM | c.5572A>C p.S1858R | Missense Mutation (SNP) | VAF 46/437 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FAT1 | c.7946A>C p.N2649T | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- FBN2 | c.2442T>G p.C814W | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FUCA2 | c.608A>G p.Q203R | Missense Mutation (SNP) | VAF 31/306 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GABRR1 | c.1433T>C p.F478S | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- GPR108 | c.686A>C p.N229T | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.14); called by mutect2, varscan2
- GRB10 | c.683A>T p.E228V | Missense Mutation (SNP) | VAF 24/271 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRB14 | c.1373T>A p.L458H | Missense Mutation (SNP) | VAF 32/237 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- GREM1 | c.250A>T p.T84S | Missense Mutation (SNP) | VAF 62/498 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- GRID2 | c.718A>G p.K240E | Missense Mutation (SNP) | VAF 38/263 reads (14%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- GTF2A1L | c.20T>G p.V7G | Missense Mutation (SNP) | VAF 36/320 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.134); called by mutect2, varscan2
- HEATR3 | c.1337G>A p.C446Y | Missense Mutation (SNP) | VAF 36/246 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HEXD | c.1151T>C p.L384P (on ENST00000327949 / NM_001369487.1; = p.W414R on NM_173620.3) | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HRG | c.1034A>C p.N345T | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- HSD17B12 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 38/366 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.169); called by muse, mutect2
- IL10RA | c.1270C>T p.H424Y | Missense Mutation (SNP) | VAF 54/432 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.637); called by muse, mutect2
- IPP | c.1069T>G p.F357V | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); called by muse, varscan2
- ISG20L2 | c.926A>C p.K309T | Missense Mutation (SNP) | VAF 20/249 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.636); called by muse, mutect2
- ITGA4 | c.2488A>C p.N830H | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ITGB8 | c.2244G>T p.K748N | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.03); called by muse, mutect2
- KCNJ3 | c.892A>C p.I298L | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- KRTAP10-4 | c.403T>C p.C135R | Missense Mutation (SNP) | VAF 72/1022 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.402); called by muse, mutect2
- LAMA3 | c.1377T>G p.I459M | Missense Mutation (SNP) | VAF 25/273 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.139); called by muse, mutect2
- LRRC57 | c.50G>C p.G17A | Missense Mutation (SNP) | VAF 36/380 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- MATN2 | c.1001A>G p.E334G | Missense Mutation (SNP) | VAF 29/316 reads (9%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- MCOLN3 | c.635+1G>A p.X212_splice | Splice Site (SNP) | VAF 40/290 reads (14%) | called by muse, mutect2, varscan2
- MUSK | c.2028C>A p.C676* | Nonsense Mutation (SNP) | VAF 32/474 reads (7%) | called by muse, mutect2
- MYCBP2 | c.6845T>C p.L2282S (on ENST00000357337; = p.L2320S on NM_015057.5) | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- MYH1 | c.2819T>A p.L940Q | Missense Mutation (SNP) | VAF 25/352 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- MYLK | c.2289A>C p.K763N | Missense Mutation (SNP) | VAF 38/330 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- MYT1 | c.2683G>A p.V895I | Missense Mutation (SNP) | VAF 26/381 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); called by muse, mutect2
- N4BP2L2 | c.605A>G p.Q202R | Missense Mutation (SNP) | VAF 39/251 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- NALCN | c.3167A>C p.D1056A | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); called by muse, mutect2
- NCKAP5 | c.930A>C p.K310N | Missense Mutation (SNP) | VAF 24/245 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- NELL1 | c.817T>C p.C273R | Missense Mutation (SNP) | VAF 44/359 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NFASC | c.3275T>C p.F1092S | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- NGEF | c.875T>C p.L292P | Missense Mutation (SNP) | VAF 44/358 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NLRP9 | c.1602A>C p.E534D | Missense Mutation (SNP) | VAF 46/347 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NOS1 | c.4240A>G p.R1414G | Missense Mutation (SNP) | VAF 35/336 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR11A1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 11/288 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2
- OR4E2 | c.436T>G p.F146V | Missense Mutation (SNP) | VAF 34/315 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR5AK2 | c.923T>C p.L308S | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- OSBPL1A | c.1095A>C p.K365N | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTOGL | c.5011T>C p.F1671L (on ENST00000547103; = p.F1662L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/265 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2
- P3H2 | c.277C>G p.P93A | Missense Mutation (SNP) | VAF 43/370 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PALB2 | c.299T>G p.L100R | Missense Mutation (SNP) | VAF 26/287 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); called by muse, mutect2
- PARP4 | c.4496G>A p.C1499Y | Missense Mutation (SNP) | VAF 43/420 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PASD1 | c.232T>G p.L78V | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.817); called by muse, mutect2
- PCLO | c.4345C>T p.Q1449* | Nonsense Mutation (SNP) | VAF 37/297 reads (12%) | called by muse, mutect2, varscan2
- PDE1B | c.1297T>G p.F433V | Missense Mutation (SNP) | VAF 38/369 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- PDZD4 | c.425T>G p.L142R | Missense Mutation (SNP) | VAF 47/355 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKHD1L1 | c.5786G>A p.G1929E | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); called by muse, mutect2
- PLCZ1 | c.465A>C p.Q155H | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- PLK1 | c.1591C>T p.Q531* | Nonsense Mutation (SNP) | VAF 31/306 reads (10%) | called by muse, mutect2
- POLR1A | c.4799T>A p.L1600H | Missense Mutation (SNP) | VAF 40/327 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PPP4R4 | c.1415T>G p.V472G | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRICKLE1 | c.23A>G p.K8R | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.104); called by mutect2, varscan2
- PRSS36 | c.572G>A p.W191* | Nonsense Mutation (SNP) | VAF 31/261 reads (12%) | called by muse, mutect2, varscan2
- QPCT | c.887A>C p.N296T | Missense Mutation (SNP) | VAF 41/315 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- R3HDM1 | c.1018T>A p.S340T | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- RALGAPA1 | c.4115T>C p.L1372P | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- RANBP17 | c.600T>A p.F200L | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASA3 | c.977A>C p.E326A | Missense Mutation (SNP) | VAF 44/395 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- RB1 | c.638T>C p.V213A | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RBBP8 | c.2304A>C p.Q768H | Missense Mutation (SNP) | VAF 34/291 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBSN | c.145A>C p.K49Q | Missense Mutation (SNP) | VAF 41/465 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2
- REG3G | c.391T>G p.F131V | Missense Mutation (SNP) | VAF 35/355 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- REPIN1 | c.751T>G p.L251V | Missense Mutation (SNP) | VAF 51/413 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- REST | c.97T>G p.L33V | Missense Mutation (SNP) | VAF 32/313 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- RIMS1 | c.4784T>G p.I1595S | Missense Mutation (SNP) | VAF 46/329 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RNF165 | c.466T>G p.L156V | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.837); called by mutect2, varscan2
- RNF220 | c.1085A>G p.K362R | Missense Mutation (SNP) | VAF 43/383 reads (11%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ROS1 | c.3319A>G p.T1107A | Missense Mutation (SNP) | VAF 30/390 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.098); called by muse, mutect2
- RTL5 | c.757A>C p.S253R | Missense Mutation (SNP) | VAF 94/495 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RYR2 | c.4993T>C p.C1665R | Missense Mutation (SNP) | VAF 50/403 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SCARF2 | c.1976C>T p.P659L | Missense Mutation (SNP) | VAF 71/407 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEC24B | c.1432A>C p.I478L | Missense Mutation (SNP) | VAF 47/365 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPING1 | c.208T>G p.S70A | Missense Mutation (SNP) | VAF 28/385 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.005); called by muse, mutect2
- SESN3 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 36/293 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SH2D3C | c.1606G>A p.G536R (on ENST00000314830 / NM_170600.3; = p.G379R on NM_005489.4) | Missense Mutation (SNP) | VAF 56/643 reads (9%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.462); called by muse, mutect2
- SLC24A5 | c.1433T>G p.L478R | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2
- SLC30A2 | c.264A>C p.E88D | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SLC47A2 | c.1658T>G p.F553C | Missense Mutation (SNP) | VAF 44/331 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- SLC6A12 | c.1786T>C p.F596L | Missense Mutation (SNP) | VAF 53/427 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLIT1 | c.2638T>C p.W880R | Missense Mutation (SNP) | VAF 42/338 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SMIM10 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 38/319 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNTG2 | c.47A>T p.Q16L | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2
- SNTG2 | c.48G>T p.Q16H | Missense Mutation (SNP) | VAF 25/298 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.03); called by muse, mutect2
- SORBS1 | c.2045A>G p.Y682C (on ENST00000361941 / NM_001034954.2; = p.Y388C on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SPAG1 | c.1850T>G p.I617S | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- SPATA31D1 | c.1489G>T p.E497* | Nonsense Mutation (SNP) | VAF 226/681 reads (33%) | called by muse, mutect2, varscan2
- SPIN3 | c.185A>G p.D62G | Missense Mutation (SNP) | VAF 108/488 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPIRE1 | c.1314C>A p.N438K (on ENST00000409402 / NM_001128626.2; = p.N424K on NM_020148.3) | Missense Mutation (SNP) | VAF 29/381 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2
- STAT1 | c.1678A>C p.S560R | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.189); called by muse, mutect2
- STON2 | c.1288A>C p.S430R (on ENST00000649389 / NM_001366849.2; = p.S373R on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/392 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- STRC | c.3325A>C p.N1109H | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- SYCP1 | c.1643T>G p.I548S | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- SYT3 | c.1467C>G p.I489M | Missense Mutation (SNP) | VAF 41/410 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- TAS2R39 | c.866A>T p.N289I | Missense Mutation (SNP) | VAF 38/365 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- TEKT5 | c.1118C>T p.T373I | Missense Mutation (SNP) | VAF 36/274 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.345); called by muse, varscan2
- TFB2M | c.1034T>G p.L345R | Missense Mutation (SNP) | VAF 21/213 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.652); called by muse, mutect2
- TFE3 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 109/479 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- TLR8 | c.904A>G p.I302V (on ENST00000218032 / NM_138636.5; = p.I320V on NM_016610.4) | Missense Mutation (SNP) | VAF 92/431 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- TMEM255A | c.21G>T p.Q7H | Missense Mutation (SNP) | VAF 42/342 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- TRAV6 | c.286A>C p.K96Q | Missense Mutation (SNP) | VAF 43/320 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- TRIM51 | c.652A>G p.R218G | Missense Mutation (SNP) | VAF 13/339 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.269); called by muse, mutect2
- TRMT2B | c.428T>C p.I143T | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.542); called by muse, mutect2
- TRPM6 | c.2522A>G p.K841R | Missense Mutation (SNP) | VAF 22/400 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2
- TSPAN12 | c.309T>G p.I103M | Missense Mutation (SNP) | VAF 33/264 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TTI1 | c.914A>C p.K305T | Missense Mutation (SNP) | VAF 32/366 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- UBE2J1 | c.737A>C p.K246T | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- UBQLN2 | c.320G>C p.R107P | Missense Mutation (SNP) | VAF 18/557 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- UNC79 | c.4776A>C p.K1592N (on ENST00000393151 / NM_001346218.2; = p.K1415N on NM_020818.5) | Missense Mutation (SNP) | VAF 54/460 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- URB1 | c.2465A>C p.H822P | Missense Mutation (SNP) | VAF 34/382 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- USP15 | c.834A>C p.E278D (on ENST00000280377 / NM_001351159.2; = p.E249D on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/273 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- USP32 | c.1793T>G p.F598C | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2
- UTRN | c.2220A>C p.E740D | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.214); called by mutect2, varscan2
- WASHC2C | c.1514A>G p.Q505R | Missense Mutation (SNP) | VAF 15/269 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.029); called by muse, mutect2
- WDFY4 | c.5660T>C p.L1887P | Missense Mutation (SNP) | VAF 31/366 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); called by muse, mutect2
- WDR19 | c.2162T>G p.L721R | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- WDR25 | c.502A>C p.K168Q | Missense Mutation (SNP) | VAF 45/363 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- WDR43 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- WIZ | c.282C>A p.C94* | Nonsense Mutation (SNP) | VAF 35/232 reads (15%) | called by muse, mutect2, varscan2
- ZAN | c.5877A>C p.K1959N | Missense Mutation (SNP) | VAF 36/324 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- ZFHX4 | c.8108A>G p.K2703R | Missense Mutation (SNP) | VAF 55/417 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ZFX | c.723T>G p.C241W | Missense Mutation (SNP) | VAF 44/498 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.908); called by muse, mutect2
- ZMYM2 | c.3251A>C p.K1084T | Missense Mutation (SNP) | VAF 40/294 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF292 | c.7846A>G p.N2616D | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.01); called by muse, mutect2
- ZNF445 | c.2767C>T p.Q923* | Nonsense Mutation (SNP) | VAF 40/426 reads (9%) | called by muse, mutect2
- ZNF658 | c.2261A>C p.K754T | Missense Mutation (SNP) | VAF 20/386 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2
- ZNF732 | c.1133A>C p.N378T | Missense Mutation (SNP) | VAF 35/332 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ABCA13 | c.14538C>T p.L4846= | Silent (SNP) | VAF 31/339 reads (9%) | catalogued as rs749577867, COSV68950484; called by muse, mutect2
- ABCC1 | c.2494T>C p.L832= | Silent (SNP) | VAF 40/395 reads (10%) | called by muse, varscan2
- ABCD1 | c.2025G>A p.G675= | Silent (SNP) | VAF 26/231 reads (11%) | called by muse, mutect2, varscan2
- AC098582.1 | c.981A>G p.L327= | Silent (SNP) | VAF 39/370 reads (11%) | called by muse, mutect2, varscan2
- ADGRE5 | c.675C>T p.V225= (on ENST00000242786 / NM_078481.4; = p.V132= on NM_001784.5) | Silent (SNP) | VAF 23/254 reads (9%) | called by muse, mutect2, varscan2
- ANK2 | c.9654T>C p.V3218= | Silent (SNP) | VAF 53/353 reads (15%) | called by muse, mutect2, varscan2
- BAG1 | c.519G>A p.L173= | Silent (SNP) | VAF 168/474 reads (35%) | called by muse, mutect2, varscan2
- C6orf58 | c.822T>C p.T274= | Silent (SNP) | VAF 33/291 reads (11%) | catalogued as rs1270771869; called by muse, mutect2, varscan2
- C8orf34 | c.219C>T p.R73= | Silent (SNP) | VAF 53/390 reads (14%) | called by muse, mutect2, varscan2
- CACNA1I | c.1326C>G p.V442= | Silent (SNP) | VAF 55/392 reads (14%) | catalogued as COSV60800598; called by muse, mutect2, varscan2
- CALHM5 | c.741A>G p.E247= | Silent (SNP) | VAF 43/335 reads (13%) | called by muse, mutect2, varscan2
- CARMIL3 | c.633G>A p.L211= | Silent (SNP) | VAF 30/320 reads (9%) | called by muse, mutect2
- CASP14 | c.327C>T p.F109= | Silent (SNP) | VAF 30/338 reads (9%) | catalogued as rs549293146, COSV55664734; called by muse, mutect2
- CD3D | c.411C>T p.A137= | Silent (SNP) | VAF 38/355 reads (11%) | catalogued as rs200520638; ClinVar: likely benign; called by muse, mutect2
- CDH11 | c.2256C>T p.A752= | Silent (SNP) | VAF 40/349 reads (11%) | catalogued as rs778715297; called by muse, mutect2, varscan2
- CDKL5 | c.1068T>C p.A356= | Silent (SNP) | VAF 52/439 reads (12%) | called by muse, mutect2, varscan2
- CMTM5 | c.336A>G p.S112= | Silent (SNP) | VAF 41/339 reads (12%) | called by muse, mutect2, varscan2
- CUBN | c.6546A>C p.S2182= | Silent (SNP) | VAF 35/384 reads (9%) | catalogued as rs1457213297, COSV64727614; called by muse, mutect2
- CYFIP2 | c.1710T>C p.T570= | Silent (SNP) | VAF 30/360 reads (8%) | called by muse, mutect2
- DEPDC1 | c.2220T>G p.A740= (on ENST00000456315 / NM_001114120.3; = p.A456= on NM_017779.6) | Silent (SNP) | VAF 26/213 reads (12%) | called by muse, varscan2
- DMD | c.10674C>G p.L3558= | Silent (SNP) | VAF 14/402 reads (3%) | catalogued as COSV100626656; called by muse, mutect2
- DMRT2 | c.993T>G p.T331= | Silent (SNP) | VAF 145/462 reads (31%) | catalogued as COSV52402163; called by muse, mutect2, varscan2
- DNAH17 | c.11500C>A p.R3834= | Silent (SNP) | VAF 26/308 reads (8%) | catalogued as rs1423867446; called by muse, mutect2
- EDRF1 | c.2031T>C p.P677= (on ENST00000356792 / NM_001202438.2; = p.P643= on NM_015608.2) | Silent (SNP) | VAF 35/272 reads (13%) | catalogued as rs368505489; called by muse, mutect2, varscan2
- EFHD1 | c.330C>T p.I110= | Silent (SNP) | VAF 41/298 reads (14%) | catalogued as rs201073311, COSV51134692; called by muse, mutect2, varscan2
- EIF2B4 | c.264G>T p.R88= (on ENST00000347454 / NM_001034116.2; = p.R87= on NM_015636.3) | Silent (SNP) | VAF 51/339 reads (15%) | called by muse, mutect2, varscan2
- EPB41L4B | c.1758A>G p.E586= | Silent (SNP) | VAF 31/340 reads (9%) | called by muse, mutect2
- FAHD2B | c.624A>C p.G208= | Silent (SNP) | VAF 39/369 reads (11%) | called by muse, mutect2, varscan2
- FAM71C | c.672C>T p.H224= | Silent (SNP) | VAF 25/317 reads (8%) | catalogued as rs139736567; called by muse, mutect2
- FCN2 | c.390T>A p.T130= | Silent (SNP) | VAF 130/406 reads (32%) | called by muse, mutect2, varscan2
- FLOT2 | c.444G>A p.E148= | Silent (SNP) | VAF 27/286 reads (9%) | catalogued as rs1446897727; called by muse, mutect2
- FNDC1 | c.2820C>T p.G940= | Silent (SNP) | VAF 38/422 reads (9%) | called by muse, mutect2
- FOXO1 | c.951T>C p.T317= | Silent (SNP) | VAF 34/360 reads (9%) | called by muse, mutect2
- GATA2 | c.264C>T p.H88= | Silent (SNP) | VAF 33/313 reads (11%) | catalogued as rs1485177083; called by muse, mutect2, varscan2
- GNAS | c.54C>T p.I18= | Silent (SNP) | VAF 36/296 reads (12%) | catalogued as COSV58328207; called by muse, mutect2, varscan2
- GRM5 | c.1056C>T p.N352= | Silent (SNP) | VAF 45/312 reads (14%) | catalogued as COSV59617455; called by muse, mutect2, varscan2
- GTDC1 | c.957A>C p.V319= | Silent (SNP) | VAF 16/288 reads (6%) | called by muse, mutect2
- HAUS6 | c.1635C>T p.A545= | Silent (SNP) | VAF 19/230 reads (8%) | catalogued as rs1404132136; called by muse, mutect2
- HCFC1 | c.3342G>A p.T1114= | Silent (SNP) | VAF 121/594 reads (20%) | catalogued as rs868910589, COSV60076034; ClinVar: likely benign; called by muse, varscan2
- HOXD4 | c.702A>C p.S234= | Silent (SNP) | VAF 38/293 reads (13%) | called by muse, mutect2, varscan2
- HTR3C | c.648G>A p.E216= | Silent (SNP) | VAF 52/332 reads (16%) | called by muse, mutect2, varscan2
- IL1RAPL1 | c.1830C>T p.T610= | Silent (SNP) | VAF 80/431 reads (19%) | called by muse, mutect2, varscan2
- KDM3B | c.2220T>A p.T740= | Silent (SNP) | VAF 39/380 reads (10%) | catalogued as rs772187981; called by muse, mutect2, varscan2
- KIAA1549 | c.771T>C p.A257= | Silent (SNP) | VAF 36/280 reads (13%) | catalogued as COSV54322209; called by muse, mutect2, varscan2
- KLHL8 | c.1674A>C p.A558= | Silent (SNP) | VAF 39/380 reads (10%) | catalogued as rs1182479424; called by muse, mutect2, varscan2
- LHX2 | c.750C>T p.D250= | Silent (SNP) | VAF 82/306 reads (27%) | catalogued as rs1175679424; called by muse, mutect2
- LRIG3 | c.46C>T p.L16= | Silent (SNP) | VAF 32/302 reads (11%) | called by muse, mutect2, varscan2
- MALRD1 | c.1146T>G p.T382= | Silent (SNP) | VAF 22/201 reads (11%) | called by muse, mutect2, varscan2
- MYH6 | c.396G>A p.P132= | Silent (SNP) | VAF 34/352 reads (10%) | catalogued as rs369139462; called by muse, mutect2
- N4BP2L2 | c.606A>G p.Q202= | Silent (SNP) | VAF 39/252 reads (15%) | called by muse, mutect2, varscan2
- NCBP3 | c.447T>G p.P149= | Silent (SNP) | VAF 22/272 reads (8%) | called by muse, mutect2
- NDUFS4 | c.51A>G p.R17= | Silent (SNP) | VAF 28/298 reads (9%) | called by muse, mutect2, varscan2
- NOTCH4 | c.195T>A p.P65= | Silent (SNP) | VAF 69/493 reads (14%) | catalogued as rs1471032428; called by muse, mutect2, varscan2
- NPPB | c.112T>C p.L38= | Silent (SNP) | VAF 33/270 reads (12%) | catalogued as rs1466301546; called by muse, mutect2, varscan2
- OMP | c.394C>T p.L132= | Silent (SNP) | VAF 38/399 reads (10%) | called by muse, mutect2
- OR1N2 | c.804T>G p.T268= | Silent (SNP) | VAF 134/388 reads (35%) | called by muse, mutect2, varscan2
- OR2AP1 | c.819T>G p.A273= | Silent (SNP) | VAF 38/284 reads (13%) | called by muse, mutect2, varscan2
- OR4D5 | c.264C>A p.G88= | Silent (SNP) | VAF 50/364 reads (14%) | catalogued as COSV58305727; called by muse, mutect2, varscan2
- OR5K1 | c.207G>A p.V69= | Silent (SNP) | VAF 43/412 reads (10%) | called by muse, mutect2, varscan2
- PAPLN | c.1557C>T p.C519= (on ENST00000554301; = p.C492= on NM_173462.4) | Silent (SNP) | VAF 47/363 reads (13%) | catalogued as rs774054825, COSV53716962; called by muse, mutect2, varscan2
- PLCL1 | c.3126G>A p.K1042= | Silent (SNP) | VAF 18/191 reads (9%) | catalogued as rs1232881166; called by muse, mutect2, varscan2
- POLR3B | c.255T>C p.P85= | Silent (SNP) | VAF 25/225 reads (11%) | called by muse, mutect2, varscan2
- POU3F4 | c.642C>T p.D214= | Silent (SNP) | VAF 80/387 reads (21%) | catalogued as COSV64538693, COSV64540131; called by muse, mutect2, varscan2
- PRDM4 | c.2106C>T p.I702= | Silent (SNP) | VAF 26/280 reads (9%) | called by muse, mutect2
- QSER1 | c.1821T>G p.S607= (on ENST00000399302; = p.S736= on NM_001076786.3) | Silent (SNP) | VAF 31/210 reads (15%) | called by muse, mutect2, varscan2
- RB1 | c.2238A>G p.E746= | Silent (SNP) | VAF 12/155 reads (8%) | catalogued as rs991505835, CD1110941; ClinVar: likely benign; called by muse, mutect2
- RBFOX3 | c.288G>A p.Q96= | Silent (SNP) | VAF 53/379 reads (14%) | called by muse, mutect2, varscan2
- RTN3 | c.468T>G p.P156= (on ENST00000377819 / NM_001265589.2; = p.P137= on NM_201428.3) | Silent (SNP) | VAF 35/349 reads (10%) | called by muse, mutect2, varscan2
- SFXN3 | c.618G>A p.V206= | Silent (SNP) | VAF 25/302 reads (8%) | called by muse, mutect2
- SHROOM2 | c.2133G>T p.P711= | Silent (SNP) | VAF 117/570 reads (21%) | called by muse, mutect2, varscan2
- SLC34A2 | c.843A>G p.K281= | Silent (SNP) | VAF 32/324 reads (10%) | catalogued as rs1285214858; called by muse, mutect2
- SMARCA1 | c.792C>T p.V264= | Silent (SNP) | VAF 31/285 reads (11%) | catalogued as rs1413392391, COSV64412872; called by muse, mutect2, varscan2
- SNRPA | c.666C>T p.L222= | Silent (SNP) | VAF 26/292 reads (9%) | called by muse, mutect2
- SPATA32 | c.972C>T p.F324= | Silent (SNP) | VAF 41/314 reads (13%) | called by muse, mutect2, varscan2
- SPHKAP | c.3807A>G p.Q1269= | Silent (SNP) | VAF 51/395 reads (13%) | called by muse, mutect2, varscan2
- ST14 | c.261G>A p.Q87= | Silent (SNP) | VAF 20/242 reads (8%) | called by muse, mutect2
- SUN3 | c.414A>G p.R138= | Silent (SNP) | VAF 39/292 reads (13%) | called by muse, mutect2, varscan2
- TK1 | c.240G>T p.L80= | Silent (SNP) | VAF 24/283 reads (8%) | called by muse, mutect2
- TMEFF1 | c.894T>G p.S298= | Silent (SNP) | VAF 12/292 reads (4%) | called by muse, mutect2
- TMEM130 | c.705G>A p.S235= | Silent (SNP) | VAF 31/229 reads (14%) | catalogued as rs77433797; called by muse, mutect2, varscan2
- TMEM145 | c.1062C>T p.A354= | Silent (SNP) | VAF 22/198 reads (11%) | called by muse, mutect2, varscan2
- TPR | c.2211A>G p.R737= | Silent (SNP) | VAF 30/260 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.43701T>C p.P14567= (on ENST00000591111; = p.P7143= on NM_003319.4) | Silent (SNP) | VAF 32/283 reads (11%) | catalogued as rs72677240; ClinVar: likely benign / uncertain significance / benign; called by muse, mutect2, varscan2
- UNC80 | c.6000T>C p.V2000= | Silent (SNP) | VAF 36/257 reads (14%) | called by muse, mutect2, varscan2
- UTP20 | c.5247A>G p.G1749= | Silent (SNP) | VAF 50/339 reads (15%) | called by muse, mutect2, varscan2
- VSX1 | c.711G>A p.L237= | Silent (SNP) | VAF 59/465 reads (13%) | catalogued as rs748180725; called by muse, mutect2, varscan2
- WDR19 | c.2028T>C p.A676= | Silent (SNP) | VAF 35/338 reads (10%) | called by muse, mutect2, varscan2
- WDR27 | c.2106C>T p.I702= | Silent (SNP) | VAF 24/200 reads (12%) | catalogued as rs777006582, COSV61216839; called by muse, mutect2, varscan2
- ZNF280C | c.1347A>G p.K449= | Silent (SNP) | VAF 39/355 reads (11%) | called by muse, mutect2, varscan2
- ZNF425 | c.1854T>G p.T618= | Silent (SNP) | VAF 49/359 reads (14%) | called by muse, mutect2, varscan2
- ZNF609 | c.4122C>T p.Y1374= | Silent (SNP) | VAF 35/320 reads (11%) | catalogued as rs1281779620; called by muse, varscan2
- ZNF649 | c.573T>C p.S191= | Silent (SNP) | VAF 48/450 reads (11%) | called by muse, mutect2
- ZNF674 | c.1134T>A p.T378= | Silent (SNP) | VAF 60/498 reads (12%) | called by muse, mutect2, varscan2
- ACVR1B | c.1261+193T>C | Intron (SNP) | VAF 24/221 reads (11%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73825576 A>C | 5'Flank (SNP) | VAF 72/314 reads (23%) | called by muse, mutect2, varscan2
- ARHGEF9 | c.-627G>T | 5'UTR (SNP) | VAF 29/410 reads (7%) | called by muse, mutect2
- ARMCX4 | c.1038+116A>C | Intron (SNP) | VAF 96/467 reads (21%) | called by muse, mutect2, varscan2
- BDKRB1 | chr14:96268495 A>G | 3'Flank (SNP) | VAF 37/309 reads (12%) | called by muse, mutect2, varscan2
- COL9A1 | c.781-77T>C | Intron (SNP) | VAF 46/371 reads (12%) | called by muse, mutect2, varscan2
- DCHS2 | n.1755G>A | RNA (SNP) | VAF 31/274 reads (11%) | catalogued as COSV59723158; called by muse, mutect2, varscan2
- ELP4 | c.1147-63910A>C | Intron (SNP) | VAF 10/194 reads (5%) | called by muse, mutect2
- NPDC1 | c.113-282C>T | Intron (SNP) | VAF 158/415 reads (38%) | catalogued as rs1349792704; called by muse, mutect2
- OPRM1 | c.-71C>T | 5'UTR (SNP) | VAF 43/332 reads (13%) | catalogued as rs1465337438; called by muse, mutect2, varscan2
- PDLIM5 | c.920+557C>T | Intron (SNP) | VAF 24/237 reads (10%) | called by muse, mutect2
- POPDC2 | c.1009+28A>G | Intron (SNP) | VAF 41/405 reads (10%) | called by muse, mutect2, varscan2
- PUS10 | c.126+935A>C | Intron (SNP) | VAF 24/297 reads (8%) | called by muse, mutect2
- TAOK2 | chr16:29989657 A>C | 3'Flank (SNP) | VAF 41/341 reads (12%) | called by muse, mutect2, varscan2
- WASF3 | c.717-914_717-913del | Intron (DEL) | VAF 41/424 reads (10%) | called by mutect2, pindel, varscan2
- ZDHHC3 | c.306+507G>A | Intron (SNP) | VAF 41/303 reads (14%) | called by muse, mutect2, varscan2
